CCDI case PBCJJB — CCDI-MCI: Molecular Characterization Initiative (MCI)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Soft Tissue Tumors and Sarcomas, NOS; Primary site: Connective, subcutaneous and other soft tissues.
https://portal.gdc.cancer.gov/cases/da8ac5c7-5cbb-4f9d-9b31-6b3312dea36f

Demographics
Sex at birth: female; Race: white.

Diagnoses (1)
1. Small cell sarcoma: ICD-O-3 morphology code: 8803/3; Tissue or organ of origin: Connective, subcutaneous and other soft tissues of head, face, and neck; Age at diagnosis: 9.5 years (3,470 days).

Biospecimens (3 samples)
- Sample 0DTC5M: Tissue type: Tumor; Specimen type: Solid Tissue.
- Sample 0DTC5U: Tissue type: Normal; Specimen type: Peripheral Whole Blood.
- Sample 0DTC60: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
